Somatic mutation profile of tumor specimen TCGA-24-1846-01A (aliquot TCGA-24-1846-01A-01W-0639-09) from TCGA case TCGA-24-1846, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.3 years (16,534 days).
Specimen TCGA-24-1846-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7e4c1ee-a56b-4a50-95a8-29a2e1e4f7e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1846-10A (Blood Derived Normal), aliquot TCGA-24-1846-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81e1a728-eb49-437f-9098-653c9c185c3d

The open-access MAF lists 110 somatic variants for this specimen: 90 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 19, Nonsense Mutation 6, Splice Site 4, Frame Shift Del 4, In Frame Del 3, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.445dup p.S149Ffs*32 | Frame Shift Ins (INS) | VAF 45/64 reads (70%) | catalogued as rs1064793929; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.3277G>C p.D1093H | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV70030708; called by muse, mutect2, varscan2
- ADSS2 | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63695297; called by muse, mutect2, varscan2
- AIFM2 | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV57159421; called by muse, mutect2, varscan2
- ALOX15 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV53398126; called by muse, mutect2, varscan2
- BCORL1 | c.5006C>A p.A1669D | Missense Mutation (SNP) | VAF 112/174 reads (64%) | SIFT tolerated (0.38); PolyPhen benign (0.093); catalogued as COSV99498805; called by muse, varscan2
- BTF3L4 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV57629913; called by muse, mutect2, varscan2
- C3AR1 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50819261; called by muse, mutect2, varscan2
- C5 | c.3486+1G>A p.X1162_splice | Splice Site (SNP) | VAF 78/82 reads (95%) | catalogued as CS135835, COSV56328066; called by muse, mutect2, varscan2
- CAB39 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV51476617; called by muse, mutect2, varscan2
- CALCOCO1 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV100017388, COSV50414563; called by muse, mutect2, varscan2
- CAVIN4 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs755935790, COSV56867244; called by muse, mutect2, varscan2
- CCDC40 | c.1046A>T p.H349L | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV53900163; called by muse, mutect2, varscan2
- CCL21 | c.334A>T p.T112S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52398821; called by muse, mutect2, varscan2
- CD101 | c.44-1G>A p.X15_splice | Splice Site (SNP) | VAF 52/140 reads (37%) | catalogued as rs999898412, COSV56718435; called by muse, mutect2, varscan2
- CLCN6 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 68/79 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770022946, COSV56738750; called by muse, mutect2, varscan2
- COL8A1 | c.2126G>A p.R709K | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV53735342; called by muse, mutect2, varscan2
- CPED1 | c.1946A>T p.E649V | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs1257320172, COSV100120290, COSV59998536; called by muse, mutect2
- CYP11B2 | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV59996168; called by muse, mutect2, varscan2
- CYTH3 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV63437519, COSV63439111; called by muse, mutect2, varscan2
- DGKG | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs148805735, COSV99402061; called by muse, mutect2, varscan2
- DLG3 | c.2038G>A p.E680K (on ENST00000374360 / NM_021120.4; = p.E375K on NM_020730.3) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52083092, COSV99530084; called by muse, mutect2, varscan2
- DNAH5 | c.4853C>G p.S1618* | Nonsense Mutation (SNP) | VAF 137/282 reads (49%) | catalogued as COSV54229172; called by muse, mutect2, varscan2
- DPRX | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 80/95 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV64949604; called by muse, mutect2, varscan2
- DYNC2H1 | c.11290A>T p.I3764F | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100517854; called by muse, mutect2
- ERP44 | c.178T>C p.F60L | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52432152; called by muse, mutect2, varscan2
- FASTK | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV99879608; called by muse, mutect2
- GIGYF1 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1354883017, COSV51942588; called by muse, mutect2, varscan2
- GPRASP2 | c.155C>G p.T52S | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV59991486; called by muse, mutect2, varscan2
- GREB1 | c.3092G>A p.G1031E | Missense Mutation (SNP) | VAF 134/155 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52188575; called by muse, mutect2, varscan2
- GRIN2A | c.2975A>C p.N992T | Missense Mutation (SNP) | VAF 81/93 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV58025535, COSV58035968; called by muse, mutect2, varscan2
- IL33 | c.511A>T p.N171Y | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs747189655, COSV67343187; called by muse, mutect2, varscan2
- IP6K2 | c.49del p.V17Sfs*68 | Frame Shift Del (DEL) | VAF 12/16 reads (75%) | catalogued as COSV60793984; called by mutect2, pindel, varscan2
- KATNAL2 | c.439C>A p.H147N (on ENST00000356157 / NM_001353899.1; = p.H75N on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs766530306, COSV99796145; called by muse, mutect2
- KCNU1 | c.2407C>A p.P803T | Missense Mutation (SNP) | VAF 51/63 reads (81%) | SIFT tolerated (0.22); PolyPhen benign (0.251); catalogued as rs770288503, COSV67756503; called by muse, mutect2, varscan2
- KDR | c.3430C>T p.H1144Y | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.442); catalogued as COSV55766555; called by muse, mutect2, varscan2
- KRT7 | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57765520, COSV57766469; called by muse, mutect2
- LAMB1 | c.4424C>G p.A1475G | Missense Mutation (SNP) | VAF 120/138 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs143261373, COSV55965271; called by muse, mutect2, varscan2
- LAMP2 | c.138G>T p.W46C | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as CM056973, COSV99568276; called by muse, mutect2
- MAGEA1 | c.502T>C p.S168P | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV100756618; called by muse, mutect2
- MED21 | c.188C>A p.A63E | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV99282013; called by muse, mutect2
- MEMO1 | c.341G>C p.W114S | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV54452662; called by muse, mutect2, varscan2
- MIA3 | c.2638C>T p.H880Y | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV60513573; called by muse, mutect2, varscan2
- MYO5A | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.272); catalogued as rs373690028; called by muse, mutect2, varscan2
- NLE1 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs1214260741; called by muse, mutect2
- NRP1 | c.428G>T p.R143I | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV55168275; called by muse, mutect2, varscan2
- OBSCN | c.9381C>G p.C3127W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV52780625; called by muse, mutect2, varscan2
- OPN1SW | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 178/508 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs779334334, COSV50821977; called by muse, mutect2, varscan2
- OR10H4 | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 110/292 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs775429459, COSV59062078; called by muse, mutect2, varscan2
- OR1E1 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 107/350 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV59459089; called by muse, mutect2, varscan2
- OTOL1 | c.1318C>A p.Q440K | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV60006945; called by muse, mutect2, varscan2
- PCDH15 | c.4513A>G p.I1505V (on ENST00000644397 / NM_001354429.2; = p.E1465= on NM_001142770.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.382); catalogued as rs1478127544, COSV64698965; called by muse, mutect2, varscan2
- PHC1 | c.485A>T p.N162I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101418538, COSV70418425; called by muse, mutect2
- PHYHIPL | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV99513275; called by muse, mutect2
- PLIN2 | c.1030A>G p.K344E | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs749702234, COSV52803373; called by muse, mutect2, varscan2
- POC1B | c.593G>C p.G198A | Missense Mutation (SNP) | VAF 120/255 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774149215, COSV57965504; called by muse, mutect2, varscan2
- PROS1 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.188); catalogued as COSV100820218; called by muse, mutect2
- PVALB | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53412466, COSV53413259; called by muse, mutect2, varscan2
- RALGAPA2 | c.2821G>C p.D941H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52499599; called by muse, mutect2, varscan2
- RAPGEF1 | c.1565_1585del p.V522_T529delinsA | In Frame Del (DEL) | VAF 51/64 reads (80%) | catalogued as COSV64699925; called by mutect2, pindel, varscan2
- RBM12 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV58292027; called by muse, mutect2, varscan2
- RXFP3 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57505982; called by muse, mutect2, varscan2
- SCAMP5 | c.566A>T p.E189V | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723795; called by muse, mutect2
- SEC61A2 | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100036271; called by muse, mutect2
- SLC12A3 | c.1934G>A p.C645Y | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52635438; called by muse, mutect2, varscan2
- SLC4A4 | c.1321C>T p.R441W (on ENST00000264485 / NM_001098484.3; = p.R397W on NM_003759.4) | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs530167253, COSV52625721; called by muse, mutect2
- SLC6A4 | c.1468A>G p.K490E | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT tolerated (0.5); PolyPhen benign (0.142); catalogued as COSV55567210; called by muse, mutect2, varscan2
- SLC6A4 | c.436G>T p.G146* | Nonsense Mutation (SNP) | VAF 116/124 reads (94%) | catalogued as COSV55565324, COSV55568818; called by muse, mutect2, varscan2
- SLIT2 | c.3126G>C p.Q1042H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV56574711, COSV56581666; called by muse, mutect2, varscan2
- SLK | c.994-2A>T p.X332_splice | Splice Site (SNP) | VAF 24/302 reads (8%) | catalogued as COSV100211576; called by muse, mutect2
- SRPX2 | c.933G>C p.Q311H | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100883998; called by muse, mutect2, varscan2
- TAF1L | c.3442C>G p.L1148V | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV54262803; called by muse, mutect2, varscan2
- TTN | c.77147C>A p.T25716K (on ENST00000591111; = p.T18292K on NM_003319.4) | Missense Mutation (SNP) | VAF 145/285 reads (51%) | PolyPhen probably damaging (0.961); catalogued as COSV60103921; called by muse, mutect2, varscan2
- TTN | c.22903G>T p.E7635* (on ENST00000591111; = p.E6708* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 87/374 reads (23%) | catalogued as COSV60103930, COSV60185375; called by muse, varscan2
- TUFT1 | c.56C>A p.A19E | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.184); catalogued as COSV99642023; called by muse, mutect2
- TXNDC12 | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV65405842; called by muse, mutect2, varscan2
- ZBED9 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV71729456; called by muse, mutect2, varscan2
- ZFAT | c.2027C>T p.S676L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV64739455; called by muse, mutect2, varscan2
- ZFHX4 | c.476A>T p.K159I | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV50764321, COSV50890424; called by muse, mutect2, varscan2
- ZFP41 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs555329332, COSV58087141, COSV58087941; called by muse, mutect2, varscan2
- ZNF22 | c.512A>C p.E171A | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1233146369, COSV53584103; called by muse, mutect2, varscan2
- ZNF24 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 120/258 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV54348623; called by muse, mutect2, varscan2
- BRCA1 | c.3458_3465dup p.D1156Cfs*2 | Nonsense Mutation (INS) | VAF 116/159 reads (73%) | called by mutect2, varscan2
- DSP | c.560_578del p.V187Gfs*3 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- FBXW12 | c.479_510del p.L160Qfs*42 | Frame Shift Del (DEL) | VAF 24/38 reads (63%) | called by mutect2, pindel, varscan2
- GRIN2D | c.1862-9_1869del p.X621_splice | Splice Site (DEL) | VAF 82/94 reads (87%) | called by mutect2, pindel, varscan2
- IGKC | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- IP6K2 | c.161_175del p.T54_E58del | In Frame Del (DEL) | VAF 27/33 reads (82%) | called by mutect2, pindel, varscan2
- NEXN | c.408_434del p.K138_R146del | In Frame Del (DEL) | VAF 58/197 reads (29%) | called by pindel, varscan2*
- RAI1 | c.3867_3874del p.T1290Pfs*55 | Frame Shift Del (DEL) | VAF 18/22 reads (82%) | called by mutect2, varscan2
- AC100868.1 | c.1182C>A p.T394= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as COSV51844071; called by muse, mutect2, varscan2
- ATP2C1 | c.2523T>C p.N841= | Silent (SNP) | VAF 70/120 reads (58%) | catalogued as COSV60757270; called by muse, mutect2, varscan2
- BCORL1 | c.5007C>A p.A1669= | Silent (SNP) | VAF 114/172 reads (66%) | catalogued as COSV99498807, COSV99500849; called by muse, varscan2
- CEP192 | c.7584A>G p.R2528= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV58065146; called by muse, mutect2, varscan2
- CIDEB | c.255C>T p.D85= | Silent (SNP) | VAF 109/215 reads (51%) | catalogued as COSV51866018; called by muse, mutect2, varscan2
- COLQ | c.1185C>T p.D395= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs548322139, COSV67524465; called by muse, mutect2, varscan2
- CPXM2 | c.1986C>T p.S662= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as rs1242161731, COSV53856219; called by muse, mutect2, varscan2
- DHX8 | c.678C>T p.S226= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as rs1463100621, COSV99292009; called by muse, mutect2
- DPP4 | c.699C>T p.V233= | Silent (SNP) | VAF 60/64 reads (94%) | catalogued as COSV62107099; called by muse, mutect2, varscan2
- GFI1 | c.141G>C p.A47= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV54042106, COSV54042858; called by muse, varscan2
- HTR1E | c.639C>T p.Y213= | Silent (SNP) | VAF 125/250 reads (50%) | catalogued as COSV59508407; called by muse, mutect2, varscan2
- MINK1 | c.3745C>T p.L1249= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV53418236; called by muse, mutect2, varscan2
- OR2B11 | c.465T>C p.S155= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as COSV59510390, COSV59511402; called by muse, mutect2, varscan2
- OR2Y1 | c.270C>G p.R90= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV57136687; called by muse, mutect2, varscan2
- PAPOLA | c.1671C>T p.N557= | Silent (SNP) | VAF 186/213 reads (87%) | catalogued as COSV53481908; called by muse, mutect2, varscan2
- SLC23A3 | c.234A>G p.G78= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as rs1559211108, COSV55407691; called by muse, mutect2, varscan2
- TAS2R7 | c.490A>C p.R164= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as COSV53689049; called by muse, mutect2, varscan2
- TFRC | c.1554T>G p.T518= | Silent (SNP) | VAF 53/524 reads (10%) | catalogued as COSV64054968; called by muse, mutect2, varscan2
- TRPM2 | c.3807G>T p.L1269= | Silent (SNP) | VAF 21/59 reads (36%) | called by mutect2, varscan2
- LPAL2 | n.162T>C | RNA (SNP) | VAF 85/148 reads (57%) | called by muse, mutect2, varscan2
